Somatic mutation profile of tumor specimen C3N-02302-02 (aliquot CPT0181610006) from CPTAC case C3N-02302, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 69.5 years (25,399 days).
Specimen C3N-02302-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 355c7ecb-e68e-43e3-9d21-0d89f08a4575.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02302-31 (Blood Derived Normal), aliquot CPT0181660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fdf5529-7b9a-4e7e-a122-72a745cb4893

The open-access MAF lists 100 somatic variants for this specimen: 57 protein-altering or splice-affecting, 24 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 24, Intron 6, 5'UTR 5, Nonsense Mutation 4, RNA 4, 3'UTR 2, Frame Shift Ins 1, 5'Flank 1, 3'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 29/488 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 33/96 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 48/184 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.370T>C p.C124R | Missense Mutation (SNP) | VAF 136/445 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909223, CD097201, CM971271, COSV64288968, COSV64294667, COSV64296578, COSV64297040; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 137/428 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCB7 | c.2225A>G p.N742S (on ENST00000373394 / NM_001271696.3; = p.N743S on NM_004299.6) | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.6); catalogued as rs377609329; called by muse, mutect2, varscan2
- ADAMTS8 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 25/536 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs771957682; called by muse, mutect2
- AOAH | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766158004, COSV99331948; called by muse, mutect2, varscan2
- ASB12 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs1485298213, COSV62856154; called by muse, mutect2
- ATG4D | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 81/394 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs199992356, COSV58763561; called by muse, mutect2, varscan2
- B4GALNT3 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs147742534; called by muse, mutect2, varscan2
- BMP5 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs148184427; called by muse, mutect2
- CACNA1A | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.915); catalogued as COSV64189509; called by muse, mutect2, varscan2
- CHD4 | c.3446G>A p.R1149Q (on ENST00000357008 / NM_001363606.2; = p.R1162Q on NM_001273.5) | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58903721; called by muse, mutect2, varscan2
- CUX1 | c.2260G>A p.V754M | Missense Mutation (SNP) | VAF 16/528 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.323); catalogued as rs782290375, COSV99472728; called by muse, mutect2
- DNAH3 | c.5000A>G p.Y1667C | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142811392; called by muse, mutect2, varscan2
- DSCAM | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773328635, COSV68634213; called by muse, mutect2
- ESS2 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.203); catalogued as rs148317214; called by muse, mutect2
- FGF23 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1297215936, COSV52975564; called by muse, mutect2, varscan2
- H1-2 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 114/433 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs751365843, COSV59191089; called by muse, mutect2, varscan2
- IRS4 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1321306927; called by muse, mutect2, varscan2
- KCND1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs782389194; called by muse, mutect2
- LAMB3 | c.186G>A p.W62* | Nonsense Mutation (SNP) | VAF 166/478 reads (35%) | catalogued as COSV61915208; called by muse, mutect2, varscan2
- LMBRD2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs780185586, COSV99683286; called by muse, mutect2, varscan2
- LRP4 | c.5626G>A p.V1876I | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs761403316, COSV66136604; ClinVar: uncertain significance; called by muse, mutect2
- MAPK7 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100218959; called by muse, mutect2
- MCHR2 | c.987C>G p.I329M | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs1562114916; called by muse, mutect2
- MGMT | c.473C>G p.A158G (on ENST00000306010; = p.A127G on NM_002412.5) | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs748040489, COSV60023574; called by muse, mutect2, varscan2
- MTREX | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57927837; called by muse, mutect2, varscan2
- NPAP1 | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201894790, COSV61505775; called by muse, mutect2, varscan2
- PIK3CA | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55878766, COSV55969430; called by muse, mutect2, varscan2
- PRRG3 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs950659306, COSV64851468; called by muse, mutect2, varscan2
- PTEN | c.211T>C p.C71R | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD110191, COSV64310010; called by muse, mutect2, varscan2
- RPS6KA6 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99425481; called by muse, mutect2
- SULT2A1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs763687131, COSV55764410; called by muse, mutect2, varscan2
- TFDP1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs751799043, COSV64739677; called by muse, mutect2, varscan2
- TFE3 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as rs781859773; called by muse, mutect2, varscan2
- TPSB2 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.073); catalogued as rs761821116; called by muse, mutect2, varscan2
- ARHGEF9 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.4130dup p.Y1377* | Nonsense Mutation (INS) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- ARID1A | c.6753dup p.T2252Yfs*26 | Frame Shift Ins (INS) | VAF 33/154 reads (21%) | called by mutect2, pindel, varscan2
- C16orf72 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 120/344 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- EDA | c.396+3G>A | Splice Region (SNP) | VAF 133/359 reads (37%) | called by muse, mutect2, varscan2
- GRM5 | c.2920G>A p.V974M (on ENST00000305447 / NM_001143831.2; = p.V942M on NM_000842.4) | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- HIVEP3 | c.2153A>G p.E718G | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HNRNPF | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 103/256 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KIAA1217 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.949); called by muse, mutect2
- KIF13B | c.1913A>G p.E638G | Missense Mutation (SNP) | VAF 209/610 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR4C5 | c.713C>A p.S238Y | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- PRKG1 | c.1996A>T p.S666C | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- RALGAPA2 | c.2440-1G>A p.X814_splice | Splice Site (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- SERINC3 | c.1224C>A p.F408L | Missense Mutation (SNP) | VAF 135/463 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SERPINA7 | c.118T>C p.Y40H | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STYK1 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 121/455 reads (27%) | called by muse, mutect2, varscan2
- TLE1 | c.1863T>A p.C621* | Nonsense Mutation (SNP) | VAF 44/153 reads (29%) | called by muse, mutect2, varscan2
- UBR3 | c.5005T>G p.L1669V | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2
- ZSCAN20 | c.790A>G p.N264D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by mutect2, varscan2
- ACSL6 | c.1011C>T p.H337= (on ENST00000379240; = p.H362= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/179 reads (23%) | catalogued as rs373328179; called by muse, mutect2, varscan2
- ACTL6B | c.843A>G p.T281= | Silent (SNP) | VAF 76/244 reads (31%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.2448G>A p.S816= (on ENST00000337414 / NM_013427.3; = p.S613= on NM_013423.3) | Silent (SNP) | VAF 42/494 reads (9%) | catalogued as rs760665247; called by muse, mutect2
- CSMD3 | c.9357C>A p.T3119= (on ENST00000297405 / NM_001363185.1; = p.T2950= on NM_052900.3) | Silent (SNP) | VAF 94/302 reads (31%) | catalogued as COSV52167249, COSV99831897; called by muse, mutect2, varscan2
- DUOXA2 | c.432C>T p.N144= | Silent (SNP) | VAF 40/574 reads (7%) | catalogued as COSV50994624, COSV99973272; called by muse, mutect2
- FEZF1 | c.1347G>A p.P449= | Silent (SNP) | VAF 22/352 reads (6%) | catalogued as rs1166770391; called by muse, mutect2
- HSD17B14 | c.759C>T p.Y253= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as rs371019958, COSV54415263; called by muse, mutect2
- IFT140 | c.3672G>A p.A1224= | Silent (SNP) | VAF 22/255 reads (9%) | catalogued as rs765766910, COSV63699170; called by muse, mutect2
- ITGAM | c.90C>T p.N30= | Silent (SNP) | VAF 61/219 reads (28%) | catalogued as rs371873765; called by muse, mutect2, varscan2
- LILRB1 | c.1302C>T p.Y434= (on ENST00000427581; = p.Y398= on NM_006669.6) | Silent (SNP) | VAF 14/312 reads (4%) | catalogued as rs140589647, COSV100207230; called by muse, mutect2
- MAP3K20 | c.2181G>A p.S727= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs761899372; called by muse, mutect2, varscan2
- NEFL | c.486C>T p.G162= | Silent (SNP) | VAF 28/348 reads (8%) | called by muse, mutect2
- OTUD5 | c.246G>T p.A82= | Silent (SNP) | VAF 173/593 reads (29%) | called by muse, mutect2, varscan2
- RORC | c.225C>A p.I75= | Silent (SNP) | VAF 55/170 reads (32%) | catalogued as COSV100562048; called by muse, mutect2, varscan2
- SALL3 | c.2142C>T p.R714= | Silent (SNP) | VAF 94/347 reads (27%) | catalogued as rs979138179, COSV101609904; called by muse, mutect2, varscan2
- SDK1 | c.288G>T p.A96= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- SHISA2 | c.324C>T p.D108= | Silent (SNP) | VAF 9/172 reads (5%) | catalogued as rs987063443; called by muse, mutect2
- SLC2A2 | c.555G>A p.R185= | Silent (SNP) | VAF 99/312 reads (32%) | catalogued as rs568964087; called by muse, mutect2, varscan2
- SPEG | c.1323G>A p.S441= | Silent (SNP) | VAF 91/282 reads (32%) | catalogued as COSV100404791; called by muse, mutect2, varscan2
- TAS2R1 | c.678G>A p.A226= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs140696180; called by muse, mutect2, varscan2
- TMEM131L | c.3906C>T p.S1302= | Silent (SNP) | VAF 110/377 reads (29%) | catalogued as rs764111784; called by muse, mutect2, varscan2
- UBAP1L | c.195C>T p.C65= | Silent (SNP) | VAF 16/388 reads (4%) | catalogued as COSV101544069; called by muse, mutect2
- VASH2 | c.361C>T p.L121= | Silent (SNP) | VAF 11/219 reads (5%) | called by muse, mutect2
- ZNF157 | c.1167T>C p.N389= | Silent (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- AC004837.1 | n.167A>T | RNA (SNP) | VAF 15/228 reads (7%) | called by muse, mutect2
- AC009533.1 | n.1165C>A | RNA (SNP) | VAF 40/718 reads (6%) | called by muse, mutect2
- AC104825.1 | n.1424G>C | RNA (SNP) | VAF 154/514 reads (30%) | called by muse, mutect2, varscan2
- ARHGEF16 | c.1305+49C>T | Intron (SNP) | VAF 70/227 reads (31%) | called by muse, mutect2, varscan2
- BBS4 | c.*122C>T | 3'UTR (SNP) | VAF 113/388 reads (29%) | catalogued as rs377069915; called by muse, mutect2, varscan2
- CCNF | c.1219-14T>C | Intron (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- CFAP94 | c.-44_-31del | 5'UTR (DEL) | VAF 90/376 reads (24%) | called by mutect2, pindel, varscan2
- FOXD3 | c.*6C>T | 3'UTR (SNP) | VAF 54/490 reads (11%) | called by muse, mutect2, varscan2
- GRK3 | c.-48C>G | 5'UTR (SNP) | VAF 72/197 reads (37%) | catalogued as rs756094047; called by muse, mutect2
- IGLL3P | n.207A>G | RNA (SNP) | VAF 46/588 reads (8%) | catalogued as rs1239047406; called by muse, mutect2
- MIR30C2 | chr6:71376915 del AT | 3'Flank (DEL) | VAF 33/105 reads (31%) | called by mutect2, pindel, varscan2
- NAA10 | c.471+29C>T | Intron (SNP) | VAF 28/498 reads (6%) | catalogued as rs782465115; called by muse, mutect2
- RAB3C | c.-16dup | 5'UTR (INS) | VAF 90/299 reads (30%) | called by mutect2, pindel, varscan2
- SLC34A1 | c.936+1331G>A | Intron (SNP) | VAF 47/185 reads (25%) | called by muse, mutect2, varscan2
- TMC8 | c.298+87C>A | Intron (SNP) | VAF 74/237 reads (31%) | called by muse, mutect2, varscan2
- TTC16 | c.1764+16G>A | Intron (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- UFD1 | c.-1C>A | 5'UTR (SNP) | VAF 124/356 reads (35%) | called by muse, mutect2, varscan2
- ZNF414 | c.-40C>T | 5'UTR (SNP) | VAF 19/173 reads (11%) | catalogued as rs1439974842; called by muse, mutect2, varscan2
- ZNF660 | chr3:44582974 del TGGAG | 5'Flank (DEL) | VAF 40/142 reads (28%) | called by mutect2, pindel, varscan2
